Surgical pathology report (de-identified scan), TCGA case TCGA-CR-7386, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-7386-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

Accession number: [REDACTED]

Final Report

DIAGNOSIS:

- 1) SOFT TISSUE, RIGHT LINGUAL ALVEOLAR MARGIN, BIOPSY: MICROSCOPIC FOCUS OF INVASIVE SQUAMOUS CELL CARCINOMA; (SEE COMMENT#1).
- 2) SOFT TISSUE, LEFT MANDIBULAR MARROW, BIOPSY: REACTIVE BONE AND FIBROSIS, NEGATIVE FOR MALIGNANCY.
- 3) SOFT TISSUE, RIGHT MANDIBULAR MARROW, BIOPSY: REACTIVE BONE AND FIBROSIS, NEGATIVE FOR MALIGNANCY.
- 4) LYMPH NODES, RIGHT LEVEL I, EXCISION: 2 OF 4 LYMPH NODES POSITIVE FOR SQUAMOUS CELL CARCINOMA (2/4), BENIGN SALIVARY GLAND TISSUE, NEGATIVE FOR MALIGNANCY.
- 5) LYMPH NODES, LEFT LEVEL IB, EXCISION: 2 OF 4 LYMPH NODES POSITIVE FOR SQUAMOUS CELL CARCINOMA (2/4), LARGEST MEASURING 1.8 CM WITH EXTRACAPSULAR EXTENSION AND FOCAL INVASION OF SALIVARY GLAND.
- 6) LYMPH NODES, LEFT LEVEL II, III, EXCISION: 6 LYMPH NODES, NEGATIVE FOR MALIGNANCY (0/6).
- 7) LYMPH NODES, LEFT LEVEL III, EXCISION: 2 LYMPH NODES, NEGATIVE FOR MALIGNANCY (0/2).
- 8) LYMPH NODE, LEFT LEVEL IB, EXCISION: 1 LYMPH NODE, NEGATIVE FOR MALIGNANCY (0/1).
- 9) SOFT TISSUE, LEVEL IB RIGHT, EXCISION: SKELETAL MUSCLE, ADIPOSE AND VASCULAR TISSUE, NEGATIVE FOR MALIGNANCY.
- 10) LYMPH NODES, RIGHT LEVEL II, EXCISION: 3 LYMPH NODES, NEGATIVE FOR MALIGNANCY (0/3).
- 11) LYMPH NODES, RIGHT LEVEL II, III, IV, EXCISION: 23 LYMPH NODES, NEGATIVE FOR MALIGNANCY (0/23).
- 12) LYMPH NODES, BILATERAL LEVEL IA, EXCISION: 4 LYMPH NODES, NEGATIVE FOR MALIGNANCY (0/4).
- 13) MANDIBLE, PARTIAL RESECTION: WELL-DIFFERENTIATED SQUAMOUS CELL CARCINOMA, 2.0 CM IN GREATEST EXTENT, LESION EXTENSIVELY INVADES THE MANDIBLE AND FOCALLY INVOLVES ADJACENT SALIVARY GLAND; LEFT AND RIGHT ENDS

[page 2 of 5]
OF MANDIBLE BONE INVOLVED BY TUMOR; LESION FOCALLY INVOLVES THE SUPERIOR SOFT TISSUE MARGIN AND EXTENDS TO WITHIN 0.1 CM OF THE LEFT AND RIGHT SOFT TISSUE MARGINS; (SEE COMMENT#2).

14) SOFT TISSUE, RIGHT ALVEOLAR BONE MARGIN, BIOPSY: NEGATIVE FOR MALIGNANCY.

COMMENT #1: Tumor is best seen in the original frozen section slides.

COMMENT#2: The right and left mandibular ends of this specimen are superseded by specimens 2 and 3 per the surgeon and these final margins are negative for tumor. This corresponds to AJCC pathologic stage IVA (pT4a,N2c,M n/a).

**Electronically Signed Out by [REDACTED]

CLINICAL DATA

Clinical Features: Unspecified

Operator: Dr. [REDACTED]

Operation: Unspecified

Operative Findings: Unspecified

Operative Diagnosis: Unspecified

Tissue Submitted: 1)right lingual alveolar margin

GROSS DESCRIPTION:

1) SOURCE: Right Lingual Alveolar Margin

Received fresh is a fragment of soft tissue measuring 1.1 x 0.4 x 0.4 cm. One side of the specimen possesses a smooth, shiny, glistening mucosal surface. The specimen is entirely submitted for frozen section evaluation. Summary of sections: 1AFSC, 1/1.

2) SOURCE: Left Mandibular Marrow Tissue

Received fresh are two fragments of soft tissue and bone measuring in aggregate 0.8 x 0.4 x 0.4 cm. The specimen is entirely submitted for frozen section evaluation. Summary of sections: 2AFSC, left mandibular marrow tissue, 2/1.

3) SOURCE: Right Mandibular Marrow Tissue

Received fresh are two fragments of bone and soft tissue measuring in aggregate 0.6 x 0.4 x 0.4 cm. The specimen is inked blue and entirely submitted for frozen section evaluation. Summary of sections: 3AFSC, right mandible marrow tissue, 2/1.

4) SOURCE: Right Level I

Received in saline are multiple fragments of fatty tissue and lymphoid tissue measuring in aggregate 8.1 x 7.3 x 1.7 cm. Present within the

[REDACTED]

[page 3 of 5]
specimen is also a small fragment of salivary gland tissue measuring 5.5 x 3.6 x 1.8 cm. Four candidate lymph nodes are identified and submitted. Representative sections of salivary gland tissue is submitted. Summary of sections: 4A, two candidate lymph nodes, two bisected, (one inked black), 4/1; 4B, two candidate lymph nodes, two bisected, (one inked black), 4C, representative salivary gland tissue, 2/1.

5) SOURCE: Left Level IB

Received fresh is one fragment of lymphoid and fatty tissue measuring 8.5 x 4.6 x 1.5 cm. The majority of the soft tissue is that of salivary gland, measuring 5.5 x 3.5 x 1.2 cm. Candidate lymph nodes are identified and submitted. Representative sections of salivary gland tissue are submitted. Summary of sections: 5A, two candidate lymph nodes, one bisected (bisected lymph node not inked), 2/1; 5B, one candidate lymph node, bisected, 1/1; 5C, 5D, one candidate lymph node, serially sectioned, 2/1 each; 5E, salivary gland tissue, 3/1.

6) SOURCE: Left Level II, III

Received in saline is one fragment of lymphoid and fatty tissue measuring 7.7 x 4.5 x 1.7 cm. Candidate lymph nodes are identified and submitted. Summary of sections: 6A, four candidate lymph nodes, 4/1; 6B, one candidate lymph node, bisected, 1/1; 6C, one candidate lymph node, bisected, 1/1.

7) SOURCE: Left Level III

Received in saline is one fragment of fatty and fibrous tissue measuring 2.4 x 1.4 x 0.7 cm. Two candidate lymph nodes are identified and submitted. The specimen is entirely submitted. Summary of sections: 7A, one candidate lymph node, bisected, 1/1; 7B, one candidate lymph node, bisected and remainder of specimen, 1/1.

8) SOURCE: Left Level IB

Received in saline is one fragment of soft tissue measuring 2.5 x 1.2 x 0.6 cm. No lymphoid candidates are identified within the specimen. The specimen is bisected and entirely submitted. Summary of sections: 8A, level IB, left lymph node, soft tissue, 1/1.

9) SOURCE: Right Level IB Soft Tissue

Received in saline is one fragment of soft tissue measuring 2.5 x 1.0 x 0.4 cm. No lymph node candidates are directly palpable or identified grossly. The specimen is entirely submitted. Summary of sections: 9A, soft tissue level 1B, 1/1.

10) SOURCE: Right Level II

Received in saline is one fragment of lymphoid and fatty tissue measuring 2.6 x 1.4 x 0.5 cm. One candidate lymph node is identified. The specimen is bisected and the specimen is entirely submitted. Summary of sections: 10A, right level II, 1/1.

[page 4 of 5]
11) SOURCE: Right Level II, III, IV

Received in saline is one fragment of lymphoid and fatty tissue measuring 6.6 x 5.2 x 0.9 cm. Candidate lymph nodes are identified and submitted. Summary of sections: 11A, candidate lymph nodes, M/1; 11B, candidate lymph nodes, M/1; 11C, candidate lymph nodes, 3/1; 11D, two candidate lymph nodes, two bisected (one inked blue), 2/1.

12) SOURCE: Bilateral Level IA

Received in saline is one fragment of lymphoid and fatty tissue measuring 4.2 x 3.0 x 1.1 cm. Candidate lymph nodes are identified and submitted. Summary of sections: 12A, three candidate lymph nodes, 3/1; 12B, one candidate lymph node, bisected, 1/1; 12C, 12D, remainder of specimen, 12C, 2/1, 12D, 1/1.

13) SOURCE: Composite Resection

Received fresh is a portion of lower mandible, skin, teeth, and associated skeletal muscle measuring 6.5 cm from anterior to posterior, 4.5 cm from superior to inferior, and 4.2 cm transversely. The portion of skin that is present is previously incised and measures 9.0 x 4.8 cm. It extends to a depth of 2.0 cm. The mandible itself measures 5.0 x 4.0 x 1.0 cm, and has four teeth attached. The teeth show variable amounts of dental caries. The muscle fragment, which is attached to the posterior aspect of the mandible, measures 4.5 x 4.0 x 3.5 cm. Also present is a small mucosal surface which is attached to the posterior/superior portion of the specimen; this measures 4.0 x 2.0 x 1.8 cm. The specimen is inked in the following manner: the right surgical margin is inked black, the left surgical margin is inked blue, the superior surgical margin is inked yellow, the inferior surgical margin is inked orange, and the deep surgical margin is inked red. The specimen is bisected to reveal a pale white mass involving the soft tissue between the teeth and the oral mucosa. This lesion measures 2.0 x 2.0 x 1.0 cm. This lesion focally penetrates into the mandible, involves the adjacent soft cutaneous tissue, and extends partially into the oral mucosa. The adjacent skeletal muscle does not appear to be grossly involved. This lesion extends to within 0.2 cm of the deep margin (red) and to within 1.8 cm of the inferior margin (orange). It appears to focally involve the left surgical margin (blue) as well as the right surgical margin (black). A representative section of the tumor is given to research. Another representative section is placed in glutaraldehyde for potential future studies. Representative sections of the specimen are submitted. Specimen containing bone are decalcified prior to submission.

Summary of sections: 13A, right mandibular margin, 1/1; 13B, left mandibular margin, 3/1; 13C, lesion invading bone, 1/1; 13D, lesion, adjacent mucosa, and deep margin, 1/1; 3E-3F, lesion and adjacent skin, bisected, bisected margin inked green, 1/1 each; 13G, inferior margin, 1/1; 13H, lesion and superior and left margin, 1/1; 13I, lesion and right surgical margin, 2/1; 13J, lesion and adjacent skin, 1/1; 13K, additional sections of lesion, 3/1; 13L, additional sections of lesion, 3/1.

14) SOURCE: Right Alveolar Bone Margin

Source 14 is received fresh labeled "right alveolar bone margin" and

[page 5 of 5]
consists of a 1.5 x 1.0 x 0.4 cm wedge of tan-red bone. The specimen is sectioned and entirely submitted following decalcification.

Summary of sections: 14A, M/1.

Dictated by [REDACTED]

Slides and report reviewed by Attending Pathologist.

SURGICAL PATHOLOGY INTRAOPERATIVE CONSULTATION

1) SOURCE: Right Lingual Aveolar Margin

FROZEN SECTION DIAGNOSIS: MICROSCOPIC FOCUS OF SUPERFICIALLY INVASIVE SQUAMOUS CELL CARCINOMA. [REDACTED]

2) SOURCE: Left Mandibular Marrow Tissue

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

3) SOURCE: Right Mandibular Marrow Tissue

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

Electronically signed by: [REDACTED]

The following special studies were performed on this case and the interpretation is incorporated in the diagnostic report above:

2xDECALCIFICATION

SNOMED: T-11180,T-11180,M-80703,

Source: NCI Genomic Data Commons file 7321621c-7772-4266-b54d-94807de1e274 (TCGA-CR-7386.484275F7-5395-4187-946C-754872305E24.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).